Surgical pathology report (de-identified scan), TCGA case TCGA-G6-A5PC, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G6-A5PC-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Carcinoma, Clear Cell
8310/3
Site: @ Kidney NOS
C64.9
JW 2/1/13

SPECIMENS:

A. LEFT KIDNEY

SPECIMEN(S):

A. LEFT KIDNEY

DIAGNOSIS:

A. KIDNEY, LEFT, NEPHRECTOMY:

- RENAL CELL CARCINOMA, CLEAR CELL TYPE, FURHMAN GRADE 4, MEASURING 6.4-CM, CONFINED TO RENAL CAPSULE
- URETERAL MARGIN NEGATIVE FOR TUMOR
- ADRENAL GLAND, NO TUMOR SEEN
- ONE HILAR LYMPH NODE NEGATIVE FOR CARCINOMA (0/1)
- SEE SYNOPTIC REPORT AND SEE NOTE.

NOTE: The tumor has solid and papillary architecture. The cells show clear cytoplasm. Part of the tumor has high grade nuclei (Furhman grade 4). The immunoprofile is compatible with clear cell carcinoma phenotype. The patient has tumor metastases to the lung ().

Dr. concurs.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A4

Population: Tumor Cells

Stain/Marker:Result: Comment:

CYTOKERATIN 7 Negative

PIN-4 HMWCK (CK5 & CK14) Negative

PIN-4 P504S Positive

PIN-4 p63 Negative

CD 10 Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimen Type: Radical nephrectomy

With adrenal gland

Laterality: Left

Tumor Site: Not specified

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 6.4cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Clear cell renal cell carcinoma 8310/3

[page 2 of 2]
Histologic Grade (Fuhrman Nuclear Grade):

G4: Nuclei bizarre and multilobated, 20 u or greater, nucleoli prominent, chromatin clumped

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Uninvolved by tumor

Regional Lymph Nodes: Negative 0 / 1

Additional Findings: None identified

Pathological Staging (pTNM): pT 1b N 0 M 1

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. LEFT KIDNEY

Received fresh labeled with patient's identification and "left kidney" is an intact kidney with attached perinephric fat weighing 322 g and measuring 12 x 7 x 5 cm. The adrenal gland is 5.2 x 2.2 x 0.5 cm; it has a golden orange coloration. The ureter is 8.3 x 0.5 cm. On opening, it is smooth and tan in coloration. There is a hilar lymph node, 0.4 cm in diameter. The capsular and perinephric fat are inked black and the kidney is bisected. There is an orange-tan mass, 6.4 x 6.2 x 5.2 cm which extends to within 0.2 cm of the capsule. It is hemorrhagic and fibrotic and pushes on the renal pelvis resulting in its dilation. Photograph is taken and tissue is procured; representatively submitted:

A1: vasculature margins

A2: bisected hilar lymph node

A3-A5: mass and relationship to capsule and perinephric fat

A6-A7: mass in relationship to renal pelvis

A8: mass and relationship to normal-appearing parenchyma

A9: normal-appearing parenchyma

A10: adrenal gland

A11: Ureter margin

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

None Given

Source: NCI Genomic Data Commons file 3a19d202-f26e-43ee-bb7b-38f8b047fb8f (TCGA-G6-A5PC.F9099C73-C2B4-47DF-B4EB-420E9B4353BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).